Somatic mutation profile of tumor specimen C3L-05478-02 (aliquot CPT0418350006) from CPTAC case C3L-05478, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 73.8 years (26,949 days).
Specimen C3L-05478-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ac23cd4-1a26-4e02-90ed-5e0ba4faabee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05478-31 (Blood Derived Normal), aliquot CPT0419900004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/663cfc55-f89c-4489-a47f-be80f5e0230e

The open-access MAF lists 281 somatic variants for this specimen: 195 protein-altering or splice-affecting, 71 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 178, Silent 71, Intron 7, Nonsense Mutation 6, Frame Shift Ins 3, 5'UTR 3, Frame Shift Del 3, In Frame Del 2, RNA 2, In Frame Ins 1, Nonstop Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC26A4 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 76/520 reads (15%) | catalogued as rs786204581, CD1211147, CM095614; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1BG | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 64/696 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs1280350283, COSV99568395; called by muse, mutect2
- ABCB4 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 99/697 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as rs761238221, CM065956, COSV55941839, COSV99710512; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAD10 | c.2866G>A p.V956M | Missense Mutation (SNP) | VAF 43/648 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs751659068; called by muse, mutect2
- ADD1 | c.721C>G p.H241D | Missense Mutation (SNP) | VAF 28/422 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs758808864; called by muse, mutect2
- ADGRG4 | c.7687G>A p.G2563R | Missense Mutation (SNP) | VAF 62/728 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1369079609, COSV54951436; called by muse, mutect2
- ATP2B2 | c.1999G>A p.D667N (on ENST00000352432; = p.D633N on NM_001683.5) | Missense Mutation (SNP) | VAF 82/449 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1043392470, COSV59496332; called by muse, mutect2, varscan2
- ATP6V1G3 | c.44A>G p.E15G | Missense Mutation (SNP) | VAF 94/696 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV55280044; called by muse, varscan2
- ATP8A2 | c.134C>T p.T45M | Missense Mutation (SNP) | VAF 31/824 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs1411651671; called by muse, mutect2
- BABAM1 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 42/439 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs765555081, COSV53106564; called by muse, mutect2
- BOC | c.964C>G p.P322A | Missense Mutation (SNP) | VAF 89/362 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs1380864431, COSV56354964; called by muse, mutect2, varscan2
- BSN | c.7096C>T p.R2366W | Missense Mutation (SNP) | VAF 44/419 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs752861640, COSV99610012; called by muse, mutect2, varscan2
- C16orf78 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 125/350 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.071); catalogued as rs373806217; called by muse, mutect2, varscan2
- CDX4 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 124/707 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100999112; called by muse, mutect2, varscan2
- CFHR5 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 78/340 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs201989784, COSV56825837; called by muse, mutect2, varscan2
- CMPK2 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 86/505 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV56774713; called by muse, mutect2, varscan2
- CMTM2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 96/591 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1386469520, COSV51749747; called by muse, mutect2, varscan2
- COL12A1 | c.8581A>C p.S2861R | Missense Mutation (SNP) | VAF 34/424 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as COSV100486671, COSV59396037; called by muse, mutect2
- CR1 | c.3310G>C p.V1104L | Missense Mutation (SNP) | VAF 123/924 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65460667; called by muse, mutect2, varscan2
- CROCC2 | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 69/402 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.594); catalogued as rs747869470; called by muse, mutect2, varscan2
- CYLC1 | c.1246A>C p.K416Q | Missense Mutation (SNP) | VAF 50/379 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV100255751; called by muse, mutect2, varscan2
- CYP8B1 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 68/443 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.692); catalogued as rs200274344; called by muse, mutect2, varscan2
- DDX49 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 84/459 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as rs566524138; called by muse, mutect2, varscan2
- DHX38 | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 60/342 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752762438, COSV104391092; called by muse, mutect2, varscan2
- DKK2 | c.72A>C p.Q24H | Missense Mutation (SNP) | VAF 28/461 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV72793705; called by muse, mutect2
- DLG5 | c.5068C>T p.R1690W | Missense Mutation (SNP) | VAF 61/948 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748404592; called by muse, mutect2
- DNAH10 | c.6500G>A p.R2167H (on ENST00000409039; = p.R2106H on NM_207437.3) | Missense Mutation (SNP) | VAF 64/458 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs766596956, COSV68988967; called by muse, mutect2, varscan2
- DNAH11 | c.7200A>C p.E2400D | Missense Mutation (SNP) | VAF 37/441 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as COSV60952126; called by muse, mutect2
- DNAH9 | c.12176C>T p.A4059V | Missense Mutation (SNP) | VAF 61/554 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs573166817, COSV52336171; called by muse, mutect2, varscan2
- DOCK10 | c.6340G>A p.V2114M | Missense Mutation (SNP) | VAF 62/463 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs547710815, COSV51366798; called by muse, mutect2, varscan2
- FABP4 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 46/444 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs772636190; called by muse, mutect2, varscan2
- FRMPD4 | c.1301G>T p.R434L | Missense Mutation (SNP) | VAF 45/373 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as rs145627278, COSV66225751; called by muse, mutect2, varscan2
- FSCB | c.1827A>C p.E609D | Missense Mutation (SNP) | VAF 91/618 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.083); catalogued as COSV100468811; called by muse, mutect2, varscan2
- GASK1B | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 95/536 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.08); catalogued as rs960814724; called by muse, mutect2, varscan2
- GCLC | c.362G>A p.R121Q (on ENST00000643939; = p.R125Q on NM_001498.4) | Missense Mutation (SNP) | VAF 93/703 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.375); catalogued as rs374816736; called by muse, mutect2, varscan2
- GUCY1A1 | c.2072A>G p.*691Wext*15 | Nonstop Mutation (SNP) | VAF 25/257 reads (10%) | catalogued as COSV56651149; called by muse, mutect2
- HADH | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 71/478 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1332610418, COSV100531350, COSV58848876; called by muse, mutect2, varscan2
- HMCN1 | c.8921T>G p.L2974R | Missense Mutation (SNP) | VAF 22/560 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99638730; called by muse, mutect2
- IQSEC3 | c.1163C>T p.P388L (on ENST00000538872 / NM_001170738.2; = p.P85L on NM_015232.1) | Missense Mutation (SNP) | VAF 92/555 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1555087328; called by muse, mutect2, varscan2
- KCNJ12 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 54/764 reads (7%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs367663948; called by muse, mutect2
- KLHL34 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 112/616 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.376); catalogued as COSV65278672; called by muse, mutect2, varscan2
- KRT33B | c.78C>G p.C26W | Missense Mutation (SNP) | VAF 37/1046 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV99290633; called by muse, mutect2
- LAMA3 | c.8204G>C p.R2735P (on ENST00000313654 / NM_198129.4; = p.R1126P on NM_000227.6) | Missense Mutation (SNP) | VAF 68/355 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52529867; called by muse, mutect2, varscan2
- LRP1B | c.8696A>G p.K2899R | Missense Mutation (SNP) | VAF 56/478 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV101255893; called by muse, mutect2, varscan2
- LRP2 | c.2063G>A p.R688H | Missense Mutation (SNP) | VAF 48/645 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs148943767, COSV55571441; ClinVar: uncertain significance; called by muse, mutect2
- LRRC10B | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 49/447 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV65223466; called by muse, mutect2, varscan2
- MAGEC2 | c.141C>A p.Y47* | Nonsense Mutation (SNP) | VAF 65/658 reads (10%) | catalogued as COSV56001975; called by muse, mutect2
- MED24 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 46/420 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768389600; called by muse, mutect2, varscan2
- MYH6 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 64/398 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs397516760, COSV62452601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO3A | c.3145A>C p.N1049H | Missense Mutation (SNP) | VAF 21/688 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56327897; called by muse, mutect2
- NBEA | c.2011C>T p.R671W | Missense Mutation (SNP) | VAF 38/242 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs906993981; called by muse, mutect2, varscan2
- NIPSNAP1 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 140/392 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1311706190, COSV53342133; called by muse, mutect2, varscan2
- NLGN4X | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 73/686 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.908); catalogued as rs770937015; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOTCH2 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs868973073, COSV99865119; called by muse, mutect2
- NTRK3 | c.2237A>G p.K746R (on ENST00000360948 / NM_001012338.2; = p.K732R on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/456 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.914); catalogued as COSV62295703, COSV62301322; called by muse, mutect2
- OR5L2 | c.34T>G p.F12V | Missense Mutation (SNP) | VAF 52/604 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65723654, COSV65724497; called by muse, mutect2
- OR6B3 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 84/462 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100097414; called by muse, mutect2, varscan2
- OR9I1 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 32/520 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs763208748, COSV56927537; called by muse, mutect2
- PCARE | c.3761dup p.E1255Rfs*38 | Frame Shift Ins (INS) | VAF 105/734 reads (14%) | catalogued as rs1294416628; called by mutect2, pindel, varscan2
- PCDH17 | c.3448C>T p.R1150W | Missense Mutation (SNP) | VAF 44/334 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs778754016, COSV64975426; called by muse, varscan2
- PCDHA10 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 80/513 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as COSV100252212, COSV56491089; called by muse, mutect2, varscan2
- PCDHAC1 | c.1582C>T p.R528W | Missense Mutation (SNP) | VAF 40/595 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV53838061, COSV99166701; called by muse, mutect2
- PCDHB4 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 97/680 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52021802, COSV52026244; called by muse, mutect2, varscan2
- PCDHGA1 | c.1984G>A p.V662M | Missense Mutation (SNP) | VAF 108/763 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV65297288; called by muse, mutect2, varscan2
- PCLO | c.11270T>C p.M3757T | Missense Mutation (SNP) | VAF 50/776 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760738539; called by muse, mutect2
- PIGQ | c.604G>C p.A202P | Missense Mutation (SNP) | VAF 48/541 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.79); catalogued as COSV99036364; called by muse, mutect2
- POP1 | c.233A>C p.K78T | Missense Mutation (SNP) | VAF 108/1334 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV62893451; called by muse, mutect2
- PPP1R42 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 34/251 reads (14%) | catalogued as rs763651966, COSV100221050; called by muse, mutect2, varscan2
- PRKAR1B | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 40/665 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs376573570, COSV104421222; called by muse, mutect2
- PRL | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 58/668 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.311); catalogued as rs765096729, COSV60592305, COSV60593038; called by muse, mutect2
- PRUNE2 | c.7478A>C p.D2493A | Missense Mutation (SNP) | VAF 25/378 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs935139790; called by muse, mutect2
- PXYLP1 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 72/499 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.347); catalogued as rs748577913; called by muse, mutect2, varscan2
- RALYL | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 50/1020 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs749865840, COSV72819608; called by muse, mutect2
- RBM41 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 71/738 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs141718313, COSV52564292; called by muse, mutect2
- RHOT1 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 36/319 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61714834, COSV61716724; called by muse, mutect2, varscan2
- ROBO2 | c.2531A>G p.N844S | Missense Mutation (SNP) | VAF 36/430 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs548687315; called by muse, mutect2
- SCART1 | c.631_633del p.N211del | In Frame Del (DEL) | VAF 111/536 reads (21%) | catalogued as rs755815290; called by pindel, varscan2
- SLC23A2 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 37/362 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756287628; called by muse, mutect2, varscan2
- SLIT2 | c.4328C>T p.T1443M | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.639); catalogued as rs377016101; called by muse, mutect2
- SMG6 | c.3962G>A p.R1321Q | Missense Mutation (SNP) | VAF 52/542 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751727076; called by muse, mutect2
- SOCS3 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 48/618 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100434539, COSV58270141; called by muse, mutect2
- SORCS1 | c.1763T>C p.V588A | Missense Mutation (SNP) | VAF 63/505 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV53880297; called by muse, mutect2, varscan2
- SOX8 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 97/651 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs373891598, COSV53510881; called by muse, mutect2, varscan2
- SPATA31A1 | c.3677C>T p.A1226V | Missense Mutation (SNP) | VAF 85/710 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1431149211; called by muse, mutect2, varscan2
- SRCAP | c.2519G>A p.R840Q | Missense Mutation (SNP) | VAF 62/461 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746341836, COSV52676931; called by muse, mutect2, varscan2
- SRRT | c.1647G>A p.T549= | Splice Region (SNP) | VAF 29/450 reads (6%) | catalogued as rs564489231; called by muse, mutect2
- TBATA | c.149A>C p.E50A | Missense Mutation (SNP) | VAF 40/666 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV54719487; called by muse, mutect2
- TEX13D | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 47/458 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.245); catalogued as rs1013521904; called by muse, mutect2, varscan2
- TLN1 | c.6626G>A p.R2209H | Missense Mutation (SNP) | VAF 106/460 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs1007964919, COSV59207754; called by muse, mutect2, varscan2
- TMEM163 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 66/345 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.05); catalogued as rs755523021, COSV56110820; called by muse, mutect2, varscan2
- TNK2 | c.1243G>C p.V415L | Missense Mutation (SNP) | VAF 97/498 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV100361735; called by muse, mutect2, varscan2
- TRAPPC12 | c.715G>A p.G239S | Missense Mutation (SNP) | VAF 44/701 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs906542332; called by muse, mutect2
- TRERF1 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 46/778 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs377409627; called by muse, mutect2
- TRPC7 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 90/515 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as rs1306693473, COSV61458534, COSV61464453; called by muse, mutect2, varscan2
- TTN | c.48383T>A p.L16128H (on ENST00000591111; = p.L8704H on NM_003319.4) | Missense Mutation (SNP) | VAF 27/362 reads (7%) | PolyPhen possibly damaging (0.708); catalogued as COSV60156585; called by muse, mutect2
- USH2A | c.3500T>C p.L1167P | Missense Mutation (SNP) | VAF 26/672 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100244996; called by muse, mutect2
- WDR64 | c.1144G>A p.V382I | Missense Mutation (SNP) | VAF 73/511 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780558450, COSV63794241; called by muse, mutect2, varscan2
- ZBTB16 | c.1745A>C p.K582T | Missense Mutation (SNP) | VAF 72/563 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV100251911, COSV60090006, COSV60099514; called by muse, mutect2, varscan2
- ZBTB37 | c.1309A>C p.S437R | Missense Mutation (SNP) | VAF 50/782 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV62933490; called by muse, mutect2
- ZKSCAN2 | c.1381G>T p.V461L | Missense Mutation (SNP) | VAF 35/592 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs765813907; called by muse, mutect2
- ZNF208 | c.2807A>C p.K936T | Missense Mutation (SNP) | VAF 63/393 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV101237161, COSV68101234, COSV68109514; called by muse, mutect2, varscan2
- ZNF536 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 54/535 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1568436551, COSV62830990; called by muse, mutect2, varscan2
- ZNF618 | c.2752G>A p.A918T (on ENST00000374126 / NM_001318042.2; = p.A825T on NM_133374.2) | Missense Mutation (SNP) | VAF 82/548 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.46); catalogued as rs764367587; called by muse, mutect2, varscan2
- ZNF76 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 56/427 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs764152482, COSV57592575; called by muse, mutect2, varscan2
- ZSCAN23 | c.515T>G p.L172R | Missense Mutation (SNP) | VAF 34/584 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV57043607; called by muse, mutect2
- ABCA13 | c.2833T>G p.L945V | Missense Mutation (SNP) | VAF 36/446 reads (8%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.527); called by muse, mutect2
- ACTN2 | c.1018C>G p.Q340E | Missense Mutation (SNP) | VAF 30/822 reads (4%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.773); called by muse, mutect2
- ADCY1 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 44/630 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.715); called by muse, mutect2
- AHNAK2 | c.5115C>A p.D1705E | Missense Mutation (SNP) | VAF 71/456 reads (16%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- BCL6B | c.357G>C p.Q119H | Missense Mutation (SNP) | VAF 42/604 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BOLL | c.511G>A p.V171I | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2
- BPNT1 | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 20/556 reads (4%) | SIFT tolerated (0.81); PolyPhen benign (0.044); called by muse, mutect2
- C6orf52 | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 28/493 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2
- C8orf34 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 55/495 reads (11%) | SIFT deleterious, low confidence (0.03); called by muse, mutect2, varscan2
- CALCRL | c.536del p.N179Ifs*12 | Frame Shift Del (DEL) | VAF 28/321 reads (9%) | called by mutect2, pindel
- CCDC151 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 36/685 reads (5%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.058); called by muse, mutect2
- CDC42BPG | c.4568G>T p.G1523V | Missense Mutation (SNP) | VAF 25/460 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.203); called by muse, mutect2
- CEP44 | c.274A>T p.T92S | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.804); called by muse, mutect2
- CEP76 | c.1886T>G p.V629G | Missense Mutation (SNP) | VAF 42/672 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- CLDN16 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 68/390 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNNM1 | c.401G>T p.R134M | Missense Mutation (SNP) | VAF 59/794 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.052); called by muse, mutect2
- COL12A1 | c.4607T>G p.V1536G | Missense Mutation (SNP) | VAF 28/449 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2
- CPS1 | c.2779C>A p.Q927K | Missense Mutation (SNP) | VAF 40/547 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.048); called by muse, mutect2
- CSMD1 | c.5751A>C p.Q1917H (on ENST00000520002; = p.Q1916H on NM_033225.6) | Missense Mutation (SNP) | VAF 18/494 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2
- DPF3 | c.840G>T p.E280D | Missense Mutation (SNP) | VAF 63/380 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- EEF1A1 | c.1082T>G p.L361W | Missense Mutation (SNP) | VAF 31/293 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, varscan2
- ELAPOR2 | c.2608G>T p.E870* (on ENST00000450689 / NM_001142749.3; = p.E703* on NM_152748.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 50/670 reads (7%) | called by muse, mutect2
- EPHA5 | c.1763T>A p.V588E | Missense Mutation (SNP) | VAF 39/397 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- EPM2A | c.406A>T p.T136S | Missense Mutation (SNP) | VAF 41/501 reads (8%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.549); called by muse, mutect2
- FAM91A1 | c.1329dup p.T444Yfs*12 | Frame Shift Ins (INS) | VAF 73/565 reads (13%) | called by mutect2, pindel, varscan2
- FOXN4 | c.1004C>G p.A335G | Missense Mutation (SNP) | VAF 37/715 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.098); called by muse, mutect2
- GALNT8 | c.213A>C p.K71N | Missense Mutation (SNP) | VAF 26/295 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.143); called by muse, mutect2
- GPR173 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 114/671 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.657); called by muse, varscan2
- GUCY1A1 | c.407T>C p.L136P | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- HCN1 | c.1612T>C p.F538L | Missense Mutation (SNP) | VAF 82/281 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- INPP5D | c.2366C>G p.P789R (on ENST00000445964 / NM_001017915.3; = p.P788R on NM_005541.5) | Missense Mutation (SNP) | VAF 34/516 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITGAV | c.2196C>G p.H732Q | Missense Mutation (SNP) | VAF 52/352 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IVL | c.1004A>G p.Q335R | Missense Mutation (SNP) | VAF 44/922 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- KBTBD2 | c.972A>C p.Q324H | Missense Mutation (SNP) | VAF 26/510 reads (5%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.948); called by muse, mutect2
- L3MBTL4 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 32/637 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2
- LBR | c.477C>G p.S159R | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- LRRIQ1 | c.3160T>C p.S1054P | Missense Mutation (SNP) | VAF 14/348 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); called by muse, mutect2
- MAP2 | c.4409T>C p.L1470P | Missense Mutation (SNP) | VAF 26/411 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2
- MED1 | c.4337G>A p.G1446D | Missense Mutation (SNP) | VAF 40/666 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.021); called by muse, mutect2
- MPZL1 | c.735C>A p.D245E | Missense Mutation (SNP) | VAF 24/674 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2
- MYO1H | c.1682G>T p.C561F | Missense Mutation (SNP) | VAF 54/365 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO3A | c.3700G>T p.E1234* | Nonsense Mutation (SNP) | VAF 87/792 reads (11%) | called by muse, mutect2, varscan2
- NCOR2 | c.2339C>T p.P780L | Missense Mutation (SNP) | VAF 78/531 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEBL | c.853A>C p.N285H | Missense Mutation (SNP) | VAF 40/620 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); called by muse, mutect2
- NHEJ1 | c.436T>A p.L146I | Missense Mutation (SNP) | VAF 32/442 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NMUR2 | c.997C>G p.R333G | Missense Mutation (SNP) | VAF 64/502 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- NRK | c.3036A>C p.K1012N | Missense Mutation (SNP) | VAF 33/623 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- NSUN3 | c.133del p.T45Hfs*27 | Frame Shift Del (DEL) | VAF 38/257 reads (15%) | called by mutect2, pindel, varscan2
- NUTM1 | c.1460G>A p.S487N | Missense Mutation (SNP) | VAF 155/527 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NXPH2 | c.225C>G p.D75E | Missense Mutation (SNP) | VAF 69/602 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR10J1 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 99/713 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- OR2B11 | c.833_835dup p.I278_S279insF | In Frame Ins (INS) | VAF 58/457 reads (13%) | called by mutect2, pindel, varscan2
- OR2B6 | c.302T>G p.L101R | Missense Mutation (SNP) | VAF 44/518 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2T11 | c.148T>C p.S50P | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5D3P | c.648A>C p.E216D | Missense Mutation (SNP) | VAF 19/389 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2
- OR8D1 | c.746T>A p.V249E | Missense Mutation (SNP) | VAF 111/532 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- OSTN | c.183A>C p.K61N | Missense Mutation (SNP) | VAF 27/743 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDH15 | c.5082C>A p.S1694R (on ENST00000644397 / NM_001354429.2; = p.S1636R on NM_001142771.2) | Missense Mutation (SNP) | VAF 44/702 reads (6%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.485); called by muse, mutect2
- PCDHAC1 | c.2185A>C p.S729R | Missense Mutation (SNP) | VAF 24/553 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- PCDHGA10 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 114/744 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- PCNX2 | c.4193A>T p.Q1398L | Missense Mutation (SNP) | VAF 76/583 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PGK2 | c.318A>C p.K106N | Missense Mutation (SNP) | VAF 38/898 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2
- PLEKHM1 | c.2610G>C p.R870S | Missense Mutation (SNP) | VAF 21/556 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- PPFIA2 | c.2894_2896del p.T965del | In Frame Del (DEL) | VAF 41/331 reads (12%) | called by mutect2, pindel, varscan2
- PTPN12 | c.690_691insA p.C231Mfs*31 | Frame Shift Ins (INS) | VAF 27/229 reads (12%) | called by mutect2, pindel, varscan2
- RGSL1 | c.3199C>A p.Q1067K | Missense Mutation (SNP) | VAF 28/616 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- RHAG | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 66/778 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.071); called by muse, mutect2
- RP1 | c.4100T>G p.V1367G | Missense Mutation (SNP) | VAF 40/504 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- RPL10A | c.640del p.Q214Sfs*? | Frame Shift Del (DEL) | VAF 62/392 reads (16%) | called by mutect2, pindel, varscan2
- RTL4 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 81/561 reads (14%) | called by muse, mutect2, varscan2
- RTN4IP1 | c.173G>C p.R58P | Missense Mutation (SNP) | VAF 67/531 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SCN9A | c.3420A>C p.E1140D (on ENST00000303354; = p.E1129D on NM_002977.3) | Missense Mutation (SNP) | VAF 50/610 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.092); called by muse, mutect2
- SLC25A45 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 100/681 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SLC30A10 | c.851C>A p.T284N | Missense Mutation (SNP) | VAF 42/878 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SLC44A5 | c.1318T>G p.F440V | Missense Mutation (SNP) | VAF 27/497 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TAOK2 | c.2610G>T p.W870C | Missense Mutation (SNP) | VAF 34/605 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.712); called by muse, mutect2
- TMCO1 | c.222G>C p.E74D (on ENST00000612311 / NM_001256164.1; = p.E23D on NM_019026.6) | Missense Mutation (SNP) | VAF 29/295 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- UNC45B | c.2494A>G p.T832A | Missense Mutation (SNP) | VAF 52/393 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, varscan2
- VANGL1 | c.1187C>G p.A396G | Missense Mutation (SNP) | VAF 41/527 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2
- VDAC2 | c.493C>A p.Q165K | Missense Mutation (SNP) | VAF 34/582 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); called by muse, mutect2
- VEPH1 | c.2414A>C p.K805T | Missense Mutation (SNP) | VAF 49/786 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- WDFY4 | c.7339A>C p.N2447H | Missense Mutation (SNP) | VAF 32/537 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); called by muse, mutect2
- YTHDF3 | c.1321A>T p.T441S | Missense Mutation (SNP) | VAF 46/450 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ZCCHC2 | c.766C>A p.Q256K | Missense Mutation (SNP) | VAF 76/546 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- ZFHX4 | c.4187A>G p.K1396R | Missense Mutation (SNP) | VAF 56/842 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZFP37 | c.854A>C p.K285T | Missense Mutation (SNP) | VAF 49/551 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2
- ZIM3 | c.536A>C p.K179T | Missense Mutation (SNP) | VAF 40/598 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.69); called by muse, mutect2
- ZNF195 | c.746G>A p.C249Y (on ENST00000399602 / NM_001130520.3; = p.C177Y on NM_007152.5) | Missense Mutation (SNP) | VAF 18/257 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZNF492 | c.338T>G p.F113C | Missense Mutation (SNP) | VAF 38/391 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2
- ZNF735 | c.407A>C p.E136A | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ACOX3 | c.108G>A p.A36= | Silent (SNP) | VAF 85/483 reads (18%) | catalogued as rs367983038; called by muse, mutect2, varscan2
- ADAMTS1 | c.2193T>G p.V731= | Silent (SNP) | VAF 34/268 reads (13%) | called by mutect2, varscan2
- ATP8B2 | c.1644C>G p.P548= (on ENST00000672630; = p.P515= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 50/782 reads (6%) | called by muse, mutect2
- BAZ2A | c.354G>C p.G118= | Silent (SNP) | VAF 65/581 reads (11%) | called by muse, mutect2, varscan2
- CACNA1C | c.672C>T p.L224= | Silent (SNP) | VAF 45/467 reads (10%) | catalogued as rs868024886, COSV59761004, COSV59780423; ClinVar: likely benign; called by muse, mutect2, varscan2
- CBLN4 | c.453G>A p.A151= | Silent (SNP) | VAF 70/937 reads (7%) | catalogued as rs760799142; called by muse, mutect2
- CCDC151 | c.45T>G p.P15= | Silent (SNP) | VAF 37/684 reads (5%) | called by muse, mutect2
- COL11A1 | c.4719G>A p.S1573= | Silent (SNP) | VAF 81/389 reads (21%) | catalogued as rs3753842, COSV100616926, COSV62171232; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CORO2B | c.1140C>A p.T380= | Silent (SNP) | VAF 30/416 reads (7%) | catalogued as COSV55957883; called by muse, mutect2
- CRYBG3 | c.5550A>G p.P1850= | Silent (SNP) | VAF 24/452 reads (5%) | called by muse, mutect2
- DNAH5 | c.7572C>T p.P2524= | Silent (SNP) | VAF 68/617 reads (11%) | catalogued as rs200333759, COSV54249252; called by muse, mutect2, varscan2
- DOCK3 | c.4734G>A p.K1578= | Silent (SNP) | VAF 27/430 reads (6%) | called by muse, mutect2
- DPYSL4 | c.81C>T p.D27= | Silent (SNP) | VAF 65/389 reads (17%) | catalogued as rs766780274, COSV58306297; called by muse, mutect2, varscan2
- DRD4 | c.1227C>T p.N409= | Silent (SNP) | VAF 37/554 reads (7%) | catalogued as rs1564914643; called by muse, mutect2
- DVL1 | c.1485C>T p.Y495= (on ENST00000378888 / NM_001330311.2; = p.Y470= on NM_004421.3) | Silent (SNP) | VAF 84/439 reads (19%) | catalogued as rs542453128; called by muse, mutect2, varscan2
- EBF1 | c.1521C>T p.N507= | Silent (SNP) | VAF 82/516 reads (16%) | catalogued as rs763968946, COSV58184625; called by muse, mutect2, varscan2
- EIF4G1 | c.2943C>T p.D981= (on ENST00000346169 / NM_198241.3; = p.D786= on NM_004953.5) | Silent (SNP) | VAF 102/568 reads (18%) | catalogued as rs374422548; called by muse, mutect2, varscan2
- ELFN1 | c.966G>A p.K322= | Silent (SNP) | VAF 62/738 reads (8%) | called by muse, mutect2
- FAM189B | c.1158C>T p.F386= | Silent (SNP) | VAF 71/1094 reads (6%) | called by muse, mutect2
- FAT2 | c.12588C>T p.S4196= | Silent (SNP) | VAF 99/514 reads (19%) | catalogued as rs1326960576, COSV55817811; called by muse, mutect2, varscan2
- FATE1 | c.186T>C p.A62= | Silent (SNP) | VAF 20/365 reads (5%) | called by muse, mutect2
- GALNT13 | c.762T>C p.T254= | Silent (SNP) | VAF 43/542 reads (8%) | catalogued as COSV101224183, COSV67224717, COSV67225652; called by muse, mutect2
- GBP1 | c.1737C>T p.L579= | Silent (SNP) | VAF 34/386 reads (9%) | catalogued as rs137909403, COSV65082987; called by muse, mutect2
- GPR139 | c.987G>A p.P329= | Silent (SNP) | VAF 21/626 reads (3%) | catalogued as rs1185530060, COSV58501525, COSV58503622, COSV58503739; called by muse, mutect2
- H2BC14 | c.24T>A p.A8= | Silent (SNP) | VAF 29/234 reads (12%) | called by muse, varscan2
- HCRTR2 | c.435G>A p.L145= | Silent (SNP) | VAF 53/487 reads (11%) | called by muse, mutect2, varscan2
- HSPA1A | c.1737G>C p.S579= | Silent (SNP) | VAF 54/1084 reads (5%) | catalogued as COSV65149083; called by muse, mutect2
- HTR3C | c.417T>C p.G139= | Silent (SNP) | VAF 123/501 reads (25%) | catalogued as rs1395959548; called by muse, varscan2
- IER2 | c.96G>A p.R32= | Silent (SNP) | VAF 34/533 reads (6%) | called by muse, mutect2
- ITIH5 | c.2655A>G p.Q885= | Silent (SNP) | VAF 30/884 reads (3%) | catalogued as COSV53661697, COSV53674841; called by muse, mutect2
- KANK1 | c.744C>T p.I248= | Silent (SNP) | VAF 121/475 reads (25%) | catalogued as COSV63209850; called by muse, mutect2, varscan2
- KAT6A | c.4119C>T p.S1373= | Silent (SNP) | VAF 81/552 reads (15%) | catalogued as rs747714674; called by muse, mutect2, varscan2
- KCNT2 | c.3306T>A p.I1102= | Silent (SNP) | VAF 55/499 reads (11%) | called by muse, mutect2, varscan2
- KIF2B | c.627G>A p.P209= | Silent (SNP) | VAF 56/452 reads (12%) | catalogued as rs1344369419, COSV52130240, COSV99275032; called by muse, mutect2, varscan2
- KRTAP17-1 | c.78G>A p.P26= | Silent (SNP) | VAF 75/793 reads (9%) | catalogued as rs1013068659, COSV61972005; called by muse, mutect2
- LAS1L | c.342C>G p.L114= | Silent (SNP) | VAF 40/550 reads (7%) | catalogued as COSV56706912; called by muse, mutect2
- MAGI3 | c.99C>T p.I33= | Silent (SNP) | VAF 57/691 reads (8%) | called by muse, mutect2
- MAP2 | c.2379A>G p.K793= | Silent (SNP) | VAF 33/446 reads (7%) | catalogued as COSV99562292; called by muse, mutect2
- MED22 | c.270C>T p.D90= | Silent (SNP) | VAF 84/391 reads (21%) | called by muse, mutect2, varscan2
- MINDY4 | c.87C>T p.T29= | Silent (SNP) | VAF 75/486 reads (15%) | called by muse, mutect2, varscan2
- NCAM2 | c.834T>G p.P278= | Silent (SNP) | VAF 77/568 reads (14%) | catalogued as COSV53067355; called by muse, mutect2, varscan2
- NPAS3 | c.339G>A p.P113= (on ENST00000356141 / NM_001164749.2; = p.P83= on NM_022123.3) | Silent (SNP) | VAF 51/377 reads (14%) | catalogued as rs199601902, COSV58109913; called by muse, mutect2, varscan2
- NPR1 | c.2031C>T p.T677= | Silent (SNP) | VAF 90/607 reads (15%) | catalogued as rs139564474, COSV64117485; called by muse, mutect2, varscan2
- NUDCD1 | c.240C>G p.T80= | Silent (SNP) | VAF 17/158 reads (11%) | called by muse, mutect2, varscan2
- OR2T4 | c.666A>C p.S222= | Silent (SNP) | VAF 20/783 reads (3%) | called by muse, mutect2
- OR5D3P | c.90A>T p.P30= | Silent (SNP) | VAF 29/467 reads (6%) | called by muse, mutect2
- P4HA1 | c.630T>C p.Y210= | Silent (SNP) | VAF 89/608 reads (15%) | called by muse, mutect2, varscan2
- POM121L12 | c.57A>G p.G19= | Silent (SNP) | VAF 56/726 reads (8%) | called by muse, mutect2
- POTEE | c.2751C>T p.C917= | Silent (SNP) | VAF 54/1440 reads (4%) | catalogued as rs761938271, COSV58223099; called by muse, mutect2
- POU3F4 | c.84G>A p.G28= | Silent (SNP) | VAF 67/593 reads (11%) | catalogued as rs375349043; called by muse, mutect2, varscan2
- PSG9 | c.525C>T p.D175= | Silent (SNP) | VAF 35/365 reads (10%) | catalogued as rs150952802, COSV52484598; called by muse, mutect2, varscan2
- PSRC1 | c.681G>A p.E227= | Silent (SNP) | VAF 50/754 reads (7%) | called by muse, mutect2
- PTPN3 | c.1038C>T p.G346= | Silent (SNP) | VAF 65/442 reads (15%) | catalogued as rs373387477, COSV52702810; called by muse, varscan2
- RAB26 | c.453C>T p.S151= | Silent (SNP) | VAF 62/595 reads (10%) | catalogued as rs1567239883, COSV99269972; called by muse, mutect2
- SHOX | c.768C>T p.S256= | Silent (SNP) | VAF 92/528 reads (17%) | catalogued as rs974381093; called by muse, mutect2, varscan2
- SLC12A1 | c.2133C>T p.C711= | Silent (SNP) | VAF 70/358 reads (20%) | called by muse, mutect2, varscan2
- SLC5A7 | c.1029T>C p.A343= | Silent (SNP) | VAF 48/463 reads (10%) | called by muse, mutect2, varscan2
- SLC6A1 | c.888C>T p.Y296= | Silent (SNP) | VAF 64/344 reads (19%) | catalogued as rs144034291; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC6A17 | c.1365C>G p.S455= | Silent (SNP) | VAF 55/622 reads (9%) | called by muse, mutect2
- SLC6A2 | c.123C>T p.G41= | Silent (SNP) | VAF 114/624 reads (18%) | catalogued as rs202149308, COSV54914036; called by muse, mutect2, varscan2
- SMG6 | c.174G>A p.R58= | Silent (SNP) | VAF 89/434 reads (21%) | catalogued as rs762565331; called by muse, mutect2, varscan2
- SOWAHA | c.195G>A p.V65= | Silent (SNP) | VAF 89/602 reads (15%) | called by muse, mutect2, varscan2
- SPANXN2 | c.105A>G p.L35= | Silent (SNP) | VAF 71/441 reads (16%) | called by muse, mutect2, varscan2
- SUN1 | c.2295T>G p.L765= (on ENST00000405266 / NM_001367651.1; = p.L645= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 50/561 reads (9%) | called by muse, mutect2
- TEX13A | c.1158C>T p.N386= | Silent (SNP) | VAF 107/548 reads (20%) | catalogued as rs782651786, COSV61150304; called by muse, mutect2, varscan2
- TRIM42 | c.1365C>T p.D455= | Silent (SNP) | VAF 36/755 reads (5%) | catalogued as rs188165530, COSV53880262, COSV53885368; called by muse, mutect2
- TRIM58 | c.924C>G p.A308= | Silent (SNP) | VAF 30/556 reads (5%) | catalogued as rs775876778, COSV100825096, COSV63569313; called by muse, mutect2
- TSPYL5 | c.99G>A p.P33= | Silent (SNP) | VAF 49/1478 reads (3%) | catalogued as COSV59071038; called by muse, mutect2
- TXLNG | c.1413T>C p.D471= | Silent (SNP) | VAF 42/762 reads (6%) | catalogued as rs1209691186; called by muse, mutect2
- WDFY2 | c.735C>T p.V245= | Silent (SNP) | VAF 26/355 reads (7%) | called by muse, mutect2
- ZNF3 | c.810C>A p.A270= | Silent (SNP) | VAF 56/948 reads (6%) | called by muse, mutect2
- ARHGEF4 | c.-155G>A | 5'UTR (SNP) | VAF 101/456 reads (22%) | catalogued as rs1203643691; called by muse, mutect2, varscan2
- BIRC7 | c.450-99C>T | Intron (SNP) | VAF 136/629 reads (22%) | catalogued as rs530112822; called by muse, mutect2, varscan2
- BNIP5 | c.*802G>T | 3'UTR (SNP) | VAF 31/671 reads (5%) | catalogued as rs561798996; called by muse, mutect2
- CLDN5 | chr22:19524478 C>G | 5'Flank (SNP) | VAF 27/571 reads (5%) | catalogued as rs1206162378; called by muse, mutect2
- GABBR1 | c.497-10C>G | Intron (SNP) | VAF 52/1140 reads (5%) | called by muse, mutect2
- GLI3 | c.367+2669A>T | Intron (SNP) | VAF 28/419 reads (7%) | catalogued as COSV67886443; called by muse, mutect2
- HELLPAR | n.204968C>G | RNA (SNP) | VAF 26/386 reads (7%) | called by muse, mutect2
- HLA-F | chr6:29727163 G>T | 3'Flank (SNP) | VAF 62/414 reads (15%) | called by muse, mutect2, varscan2
- NEDD4L | c.297+4663C>T | Intron (SNP) | VAF 65/390 reads (17%) | called by muse, mutect2, varscan2
- OSGIN1 | n.1062G>C | RNA (SNP) | VAF 70/481 reads (15%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-4303G>A | Intron (SNP) | VAF 63/515 reads (12%) | catalogued as rs9292610; called by muse, mutect2, varscan2
- TTN | c.34265-4240A>C | Intron (SNP) | VAF 24/542 reads (4%) | called by muse, mutect2
- TTN | c.10360+1798A>C | Intron (SNP) | VAF 16/404 reads (4%) | catalogued as COSV60139727; called by muse, mutect2
- VPS11 | c.-581C>T | 5'UTR (SNP) | VAF 48/510 reads (9%) | called by muse, mutect2
- ZNF493 | c.-84_-74del | 5'UTR (DEL) | VAF 37/296 reads (13%) | called by mutect2, pindel, varscan2
